Somatic mutation profile of tumor specimen TCGA-VQ-A8PC-01A (aliquot TCGA-VQ-A8PC-01A-11D-A397-08) from TCGA case TCGA-VQ-A8PC, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.5 years (23,912 days).
Specimen TCGA-VQ-A8PC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88d07b74-c6c1-42fd-ac9c-79ca9dc27521.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PC-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PC-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3202740-faf2-45a9-b2fc-a49d50567f25

The open-access MAF lists 134 somatic variants for this specimen: 102 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 30, Nonsense Mutation 4, RNA 2, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAP1L3 | c.1505A>T p.K502M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV59073839, COSV59074072, COSV59075074; called by muse, mutect2, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99341925; called by muse, mutect2
- ACLY | c.1003G>C p.G335R | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100709879; called by muse, mutect2
- ADGRB3 | c.1252A>C p.N418H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV101001796; called by muse, mutect2, varscan2
- AFF2 | c.3539A>G p.K1180R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53982197, COSV99665881; called by muse, mutect2, varscan2
- AHNAK2 | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100318753; called by muse, mutect2
- AKAP6 | c.6337T>G p.L2113V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55221082, COSV99797570; called by muse, mutect2, varscan2
- ATG2A | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as COSV101034743; called by muse, mutect2
- ATM | c.1514T>G p.F505C | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555071109, CD122165, CM1314103, COSV99591547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.3794A>G p.N1265S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs371187842, COSV100971322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICC1 | c.356A>C p.K119T | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100874899; called by muse, mutect2
- BRD3 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.138); catalogued as COSV100325482; called by muse, mutect2, varscan2
- CASP4 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV101274206; called by muse, mutect2, varscan2
- CCDC151 | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV99371895; called by muse, mutect2, varscan2
- CCDC34 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100156676; called by muse, mutect2, varscan2
- CCDC85A | c.1636G>T p.G546* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101339543, COSV68155586; called by muse, mutect2
- CD200 | c.725T>C p.L242P (on ENST00000473539 / NM_001004196.3; = p.L217P on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.505); catalogued as COSV100238466; called by muse, mutect2, varscan2
- CFAP44 | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99870242; called by muse, mutect2
- CLDN6 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1336387560, COSV100172328; called by muse, mutect2, varscan2
- COL8A1 | c.643T>G p.L215V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as COSV99658326; called by muse, mutect2, varscan2
- CPA6 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV99914527; called by muse, mutect2
- DCAF12L2 | c.1142A>T p.K381M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100758799, COSV63581446, COSV63581842; called by muse, mutect2, varscan2
- DCC | c.1634T>G p.L545R | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV59086205; called by muse, mutect2, varscan2
- DIAPH3 | c.1277G>T p.S426I (on ENST00000400324 / NM_001042517.2; = p.S163I on NM_030932.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99934350; called by muse, mutect2, varscan2
- DNAH11 | c.6212A>C p.K2071T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60965483; called by muse, mutect2, varscan2
- DNAH9 | c.11537C>A p.T3846K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV52342349, COSV99307701; called by muse, mutect2
- DNM3 | c.608T>G p.V203G | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100798598; called by muse, mutect2, varscan2
- ELOA2 | c.1664T>C p.L555P | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs923006254, COSV99797742; called by muse, mutect2, varscan2
- EPHA6 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as COSV67572128; called by muse, mutect2, varscan2
- FABP12 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs377161218; called by muse, mutect2, varscan2
- FAM135B | c.4061T>G p.V1354G | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99426853; called by muse, mutect2, varscan2
- FPR2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs750225501, COSV60674565; called by muse, mutect2, varscan2
- FREM2 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs755744742, COSV54831109; called by muse, mutect2, varscan2
- FTHL17 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1329096769, COSV100784389; called by muse, mutect2
- GNA15 | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as COSV99505376; called by muse, mutect2
- GPRC5B | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs371774176; called by muse, mutect2, varscan2
- GRM1 | c.1203A>C p.E401D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.446); catalogued as COSV99266979; called by muse, mutect2, varscan2
- GRM5 | c.2423T>G p.L808R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100554140; called by muse, mutect2, varscan2
- HIVEP3 | c.1969A>G p.N657D | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.874); catalogued as COSV99913733; called by muse, mutect2
- HMCN1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54953884, COSV99634592; called by muse, mutect2, varscan2
- HSF2 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.364); catalogued as rs1282501997, COSV100869710, COSV100869714; called by muse, mutect2
- HSPA8 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57082798; called by muse, mutect2
- HTR1A | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1424623447, COSV100109249; called by muse, mutect2, varscan2
- IBA57 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as COSV100812793; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs754881340; called by muse, mutect2
- IL7R | c.1217T>G p.L406R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.861); catalogued as COSV57405878, COSV57406361; called by muse, mutect2, varscan2
- ITPR1 | c.2920A>G p.K974E (on ENST00000354582; = p.K959E on NM_002222.7) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100232900; called by muse, mutect2, varscan2
- KERA | c.524A>C p.N175T | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99899544; called by muse, mutect2
- KIAA1614 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100799875; called by muse, mutect2, varscan2
- LAMA1 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766888109, COSV101057499; called by muse, mutect2, varscan2
- LMCD1 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99337809; called by muse, mutect2, varscan2
- LRP1B | c.1844G>T p.W615L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101260000; called by muse, mutect2, varscan2
- MAGEA4 | c.539T>G p.V180G | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99367684; called by muse, mutect2, varscan2
- MAL2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99411165; called by muse, mutect2, varscan2
- MEX3B | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs143849049; called by muse, mutect2, varscan2
- NDUFB11 | c.373C>A p.L125I (on ENST00000377811 / NM_001135998.3; = p.L135I on NM_019056.6) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs1556760609, COSV99333359; called by muse, varscan2
- NRG3 | c.1759C>A p.L587M (on ENST00000404547 / NM_001370084.1; = p.L563M on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.075); catalogued as COSV100930828; called by muse, mutect2, varscan2
- OR4D5 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as rs779387587, COSV100190151, COSV58308183; called by muse, mutect2, varscan2
- OR52E4 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100389349; called by muse, mutect2, varscan2
- OR52E4 | c.259T>A p.F87I | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100389351, COSV57623800, COSV57625175; called by muse, mutect2, varscan2
- OR5J2 | c.810A>C p.Q270H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV56620506, COSV56620552; called by muse, mutect2
- OR6K3 | c.823T>G p.L275V (on ENST00000368146; = p.L259V on NM_001005327.2) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- PCDH15 | c.5098C>G p.L1700V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as rs1403448668, COSV100226450; called by muse, mutect2
- PCDH17 | c.2264del p.G755Afs*26 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as COSV64980517; called by mutect2, pindel, varscan2
- PCDH19 | c.2974G>A p.A992T (on ENST00000373034 / NM_001184880.2; = p.A944T on NM_020766.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs745510287, COSV55259083, COSV99720002; called by mutect2, varscan2
- PDE11A | c.1414A>G p.N472D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99614459; called by muse, mutect2, varscan2
- PICALM | c.1132T>A p.S378T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV100708177; called by muse, mutect2, varscan2
- PLXNA1 | c.5226C>A p.S1742R | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99303949; called by muse, mutect2, varscan2
- POC1B | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as rs908199122, COSV100544459; called by muse, mutect2
- PODN | c.1273G>A p.G425S (on ENST00000395871; = p.G377S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100439786; called by muse, mutect2
- POGK | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100902585; called by muse, mutect2, varscan2
- PPFIA4 | c.3027T>A p.N1009K (on ENST00000447715; = p.N1010K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV99690877; called by muse, mutect2, varscan2
- PSG2 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV100283682; called by muse, mutect2, varscan2
- RARA | c.1061C>A p.P354Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99565350; called by muse, mutect2, varscan2
- RAVER1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99349247; called by muse, mutect2, varscan2
- RPL23 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1026714475, COSV55561283; called by muse, mutect2, varscan2
- RSPH10B | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs374427152; called by muse, mutect2, varscan2
- RSPO1 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.996); catalogued as COSV100740687; called by muse, mutect2, varscan2
- SACS | c.9744G>A p.W3248* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV66539593; called by muse, mutect2, varscan2
- SAMD9L | c.1415A>G p.Q472R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.494); catalogued as COSV100561084; called by muse, mutect2, varscan2
- SLC17A9 | c.498G>A p.G166= | Splice Region (SNP) | VAF 22/118 reads (19%) | catalogued as COSV100947804; called by muse, mutect2, varscan2
- SLC4A3 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs1298958577, COSV99813134; called by muse, mutect2, varscan2
- SLU7 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV99775787; called by muse, mutect2, varscan2
- SOHLH2 | c.320T>G p.F107C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100499517; called by muse, mutect2, varscan2
- SORCS1 | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99549685; called by muse, mutect2
- SPANXN3 | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV65139944, COSV65140045; called by muse, mutect2, varscan2
- SPPL2A | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.16); catalogued as rs539112496, COSV99961792; called by muse, mutect2
- ST8SIA5 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV59330302; called by muse, mutect2, varscan2
- THSD7B | c.1179A>C p.E393D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55695918; called by muse, mutect2, varscan2
- TRPC6 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100723745; called by muse, mutect2, varscan2
- TTN | c.16276C>T p.R5426W (on ENST00000591111; = p.R4499W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | PolyPhen possibly damaging (0.528); catalogued as rs377193479; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TYW1 | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.081); catalogued as COSV100659037; called by muse, mutect2, varscan2
- UBE2R2 | c.577A>C p.K193Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99602433; called by muse, varscan2
- UNC80 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs367659566; called by muse, mutect2, varscan2
- USP31 | c.1396A>G p.T466A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.191); catalogued as rs776626131, COSV99565749; called by muse, mutect2, varscan2
- ZNF573 | c.1537C>G p.L513V (on ENST00000536220 / NM_001172692.1; = p.L455V on NM_152360.3) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs561805450, COSV100265801; called by muse, mutect2, varscan2
- ZNF620 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100094152; called by muse, mutect2, varscan2
- ANKRD20A4P | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by mutect2, varscan2
- IMPDH2 | c.215_216dup p.V73Qfs*9 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- ZAN | c.1838_1879del p.N613_P626del | In Frame Del (DEL) | VAF 20/167 reads (12%) | called by muse*, mutect2
- ZNF26 | c.1581A>G p.I527M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CDYL2 | c.483C>T p.A161= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs149557557; called by muse, mutect2, varscan2
- CEP350 | c.4488T>G p.T1496= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100855121; called by muse, varscan2
- CRYBB1 | c.528C>T p.V176= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53232673, COSV99316180; called by muse, mutect2, varscan2
- CYLC1 | c.153T>C p.P51= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100255296; called by muse, mutect2, varscan2
- DSG1 | c.1368C>T p.L456= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs150549762, COSV99935549; called by muse, mutect2, varscan2
- FRMPD1 | c.435C>T p.T145= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs774428491, COSV66702482; called by muse, mutect2, varscan2
- FSIP2 | c.17076T>G p.S5692= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1435338792, COSV100556151; called by muse, mutect2, varscan2
- H3C10 | c.153G>A p.E51= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV60797069, COSV60797079; called by muse, mutect2, varscan2
- LRP1B | c.2799T>A p.S933= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV101259999; called by muse, mutect2, varscan2
- LYST | c.11223T>C p.P3741= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV101090138; called by muse, mutect2
- NEGR1 | c.1023T>G p.S341= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100165634, COSV60844622; called by muse, mutect2, varscan2
- NTRK2 | c.1971C>G p.A657= (on ENST00000323115 / NM_001369534.1; = p.A673= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99458083; called by muse, mutect2
- NUAK2 | c.1281G>A p.P427= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs778951173, COSV100904142; called by muse, mutect2, varscan2
- PRPF19 | c.696C>T p.S232= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs759269639, COSV99920751; called by muse, mutect2, varscan2
- PTPRZ1 | c.3537A>G p.E1179= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV101100728, COSV66445367; called by muse, mutect2, varscan2
- REG1A | c.147C>T p.Y49= | Silent (SNP) | VAF 32/203 reads (16%) | catalogued as COSV99286958; called by muse, mutect2, varscan2
- RPAP1 | c.3699C>T p.L1233= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100427308; called by muse, mutect2, varscan2
- SEMG1 | c.312A>G p.Q104= | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as rs1431009588, COSV99725506; called by muse, mutect2
- SLC18A3 | c.1440C>T p.S480= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV60335491; called by muse, mutect2
- SLC22A6 | c.1623A>G p.R541= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100842911; called by muse, mutect2
- SLC22A7 | c.459C>T p.A153= (on ENST00000372585 / NM_153320.2; = p.A151= on NM_006672.3) | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs1397941830, COSV65353694; called by muse, mutect2
- SLC44A3 | c.1179C>T p.F393= (on ENST00000271227 / NM_001114106.3; = p.F345= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV99598585; called by muse, mutect2, varscan2
- SPAG17 | c.4824G>A p.L1608= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100310273; called by muse, mutect2, varscan2
- SPATA31D1 | c.3339A>G p.A1113= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100783022; called by muse, mutect2, varscan2
- ST8SIA3 | c.507G>A p.G169= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs905465848, COSV60653621, COSV60654042; called by muse, mutect2, varscan2
- TRPM2 | c.1026C>T p.N342= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs747609422, COSV55977381; called by muse, mutect2, varscan2
- TYR | c.942T>G p.S314= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV99635151; called by muse, mutect2, varscan2
- UBA6 | c.87G>A p.L29= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1422521842, COSV100451845; called by muse, mutect2, varscan2
- UNC79 | c.7068C>A p.T2356= (on ENST00000393151 / NM_001346218.2; = p.T2179= on NM_020818.5) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99829620; called by muse, mutect2, varscan2
- USP38 | c.2949C>T p.D983= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100189444; called by muse, mutect2, varscan2
- ATP6AP1L | n.1443A>C | RNA (SNP) | VAF 22/116 reads (19%) | catalogued as COSV101205157; called by muse, mutect2, varscan2
- SNORD116-4 | n.67A>T | RNA (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
